Surgical pathology report (de-identified scan), TCGA case TCGA-24-2023, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2023-01A (Primary Tumor).

[page 1 of 8]
DIAGNOSTICS

TCGA-24-2023

OVARY, LEFT, SALPINGO-OOPHORECTOMY - POORLY DIFFERENTIATED
PAPILLARY SEROUS ADENOCARCINOMA, 9 CM
- TUMOR IS PRESENT ON THE OVARIAN SURFACE

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- TUBO-OVARIAN ADHESIONS

OVARY, RIGHT, SALPINGO-OOPHORECTOMY - POORLY DIFFERENTIATED
PAPILLARY SEROUS ADENOCARCINOMA
- TUMOR IS PRESENT ON THE OVARIAN
SURFACE

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA
COMPLETELY REPLACING FALLOPIAN TUBE LUMEN

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- FOCAL ACUTE AND CHRONIC INFLAMMATION WITH
GIANT CELL REACTION

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- INACTIVE ENDOMETRIUM
- ENDOMETRIAL POLYP

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MULTIPLE LEIOMYOMAS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY - (SEE COMMENT)

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION - NO CARCINOMA
IDENTIFIED IN FIVE LYMPH NODES (0/5)

LYMPH NODES, RIGHT OBTURATOR, EXCISION - NO CARCINOMA IDENTIFIED
NINE LYMPH NODES (0/9)

LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION - NO CARCINOMA
IDENTIFIED IN FOUR LYMPH NODES (0/4)

LYMPH NODES, LEFT OBTURATOR, EXCISION - NO CARCINOMA IDENTIFIED
THREE LYMPH NODES (0/3)

[page 2 of 8]
GROSS (continued)

tumor nodules penetrate through the appendix wall and into the lumen. [REDACTED]

The fifth container is labelled "tumor tissue." It consists of multiple papillary hemorrhagic tissue fragments that in aggregate measure approximately 12 cc. [REDACTED]

The sixth container is labelled "omentum." It consists of a fragment of fibroadipose tissue that in aggregate measure 18 x 15 x 4 cm, and which is practically totally replaced by tumor nodules. [REDACTED]

COMMENT

There is extensive moderately to poorly differentiated papillary serous adenocarcinoma involving both ovaries, serosal surfaces of the right and left fallopian tubes, omentum, and the separately submitted specimen labeled "tumor tissue." The tumor shows significant pleomorphism, high mitotic rate, and extensive lymphovascular involvement. The tumor also involves the serosa, muscularis, submucosa and the mucosa of the appendix. The endometrium is inactive and leiomyomas are present in the myometrium. There are no significant pathologic changes in the cervix. [REDACTED]

{End of Report}

[page 3 of 8]
DIAGNOSIS (continued)

LYMPH NODES, PERIAORTIC, EXCISION - NO CARCINOMA IDENTIFIED IN
FOUR LYMPH NODES (0/4)

OMENTUM, OMENTECTOMY - MATURE ADIPOSE TISSUE WITH A SINGLE FOCUS
OF METASTATIC ADENOCARCINOMA
- MESOTHELIAL HYPERPLASIA
- MILD ACUTE AND CHRONIC INFLAMMATION

SOFT TISSUE, RIGHT GUTTER (SLIDE H), BIOPSY
- FIBROADIPOSE TISSUE WITH MESOTHELIAL HYPERPLASIA

SOFT TISSUE, LEFT GUTTER (SLIDE J), BIOPSY
- FIBROADIPOSE TISSUE WITH ACUTE AND CHRONIC
INFLAMMATION
- NO CARCINOMA IDENTIFIED

SOFT TISSUE, RIGHT GUTTER (SLIDE K), BIOPSY
- FIBROUS TISSUE WITH MILD CHRONIC INFLAMMATION
- NO CARCINOMA IDENTIFIED

SOFT TISSUE, DIAPHRAGM, BIOPSY - FIBROADIPOSE TISSUE AND SKELETAL
MUSCLE WITH MILD CHRONIC INFLAMMATION
- NO CARCINOMA IDENTIFIED

SOFT TISSUE, ANTERIOR CUL-DE-SAC (SLIDE M), BIOPSY
- FIBROADIPOSE TISSUE WITH NO CARCINOMA IDENTIFIED

SOFT TISSUE, ANTERIOR CUL-DE-SAC (SLIDE N), BIOPSY
- FIBROADIPOSE TISSUE WITH NO CARCINOMA IDENTIFIED

SOFT TISSUE, POSTERIOR CUL-DE-SAC (SLIDE O), BIOPSY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

SOFT TISSUE, POSTERIOR CUL-DE-SAC (SLIDE P), BIOPSY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

SPECIMEN(S) SUBMITTED

Part 1: FS, OVARY, LEFT
Part 2: X, ADNEXA, LEFT
Part 3: ADNEXA, RIGHT, UTERUS AND CERVIX
Part 4: RIGHT EXTERIOR ILIAC
Part 5: RIGHT OBTURATOR
Part 6: LEFT EXTERIOR ILIAC
Part 7: LEFT OBTURATOR

[page 4 of 8]
SPECIMEN(S) SUBMITTED

Part 8: PERI-AORTIC
Part 9: OMENTUM
Part 10: DIAPHRAGM
Part 11: RIGHT GUTTER
Part 12: LEFT GUTTER
Part 13: LEFT GUTTER
Part 14: RIGHT GUTTER
Part 15: ANTERIOR CULDESAC
Part 16: ANTERIOR CULDESAC
Part 17: POSTERIOR CULDESAC
Part 18: ANTERIOR CULDESAC

HISTORY

The patient is a [REDACTED] with a left adnexal mass. Operative procedure: Exploratory laparotomy, total abdominal hysterectomy, left salpingo-oophorectomy, right salpingo-oophorectomy, lymph node dissection, omentectomy, biopsy of diaphragm, pericolic gutters and pelvic biopsies.

FROZEN

Ovary, left salpingo-oophorectomy - "Papillary carcinoma" by [REDACTED]

GROSS

The specimens are received in eighteen containers of formalin, each labeled with the patient's name. The first container is labeled "FS" and contains a single yellow-tan tissue fragment measuring 2.7 x 2 x 0.2 cm. [REDACTED]

The second container is labeled "X1, #1, left adnexa" and contains an ovary and adjacent fallopian tube. The ovary measures 11 x 9 x 8 cm. Within the ovary are multiple cystic cavities. One or more of the cystic cavities is involved by a mass of yellow, papillary tumor that measures 9 x 8 x 6 cm. Hemorrhage and necrosis appear to be present within the tumor tissue. Gross photos taken. The adjacent fallopian tube measures 6.5 cm in length and 0.6 cm in average diameter. It is adherent to the ovary at its distal end but otherwise is grossly unremarkable. Tumor appears to extend to within less than 1 mm of the surface but is not definitively at the surface grossly. Normal ovarian stroma is not identified.

[page 5 of 8]
GROSS (Continued)

Some of the cyst walls are smooth and others have small nodules on them. Labeled XA through XM, sections of the ovary and fallopian tube.

The third container is labeled "#2, right adnexa, uterus and cervix." The main portion of the specimen within the container is an ovary with adjacent segment of fallopian tube. The ovary is largely cystic and measures ~9 x 7 x 4 cm. The cyst has been opened prior to receipt and therefore the measurements may no longer be accurate. The external surface of the ovary shows multiple tumor nodules, the largest measuring 4 x 2.5 x 1.5 cm. This nodule has been broken prior to receipt and papillary tumor tissue is present at the surface. A second nodule of similar size is present adjacent to the cyst and appears to be completely enclosed by the ovarian serosa. Adjacent to the ovary is the fallopian tube which has been divided 2 cm from its fimbriated end. The portion proximal to the point of division measures 3 cm in length and 0.5 cm in average diameter. There is a nodular thickening of the fallopian tube near the point of division and here the fallopian tube measures 0.8 cm in diameter. Tumor does not appear to involve the fallopian tube directly. The largest ovarian cyst is lined by smooth epithelium over most of its surface, but there are multiple nodular excrescences present on one side, covering an area that measures ~4 x 4 cm. Labeled: A1 and A2, A4 and A5, sections of right ovary; A3, and fallopian tube. Gross photo taken.

Also within the container is a 56 gm uterus, measuring 8 x 4 x 3 cm. The serosal surface is tan and leathery. On the right posterior surface, near the cervix is an adhesion with a fleshy nodule, measuring 1 x 0.5 x 0.3 cm attached to it. This may represent a piece of tumor. The ectocervical mucosa is tan and smooth with petechial hemorrhages around its periphery. The endocervical canal is moderately furrowed. The uterine cavity measures 7.5 cm in length by 3 cm in maximum width. The endometrium measures 1 to 2 mm in thickness. Attached to the posterior surface of the endometrium is a polyp that measures 4 x 1.5 x 0.6 cm. Within the myometrium in the left subserosal region is a well-circumscribed, white, leiomyoma, measuring 1 x 0.7 x 0.5 cm. It has a firm, whorled white interior. Labeled A6, anterior cervix; A7, posterior cervix; A8, anterior endomyometrium; A9, posterior endomyometrium including polyp. Additional benign-appearing leiomyomata measuring up to 0.9 cm in greatest dimension are identified. Each is firm, white, whorled, and well circumscribed. None of the leiomyomas has any evidence of hemorrhage or necrosis. Labeled A10, sections of leiomyomas.

[page 6 of 8]
GROSS (continued)

2.

The fourth container is labeled "right external iliac lymph nodes" and contains fibroadipose tissue with one large lymph node, measuring 3.5 x 0.7 x 0.5 cm and several smaller lymph nodes. The large lymph node is bisected and labeled B1; B2, remaining lymph nodes. [REDACTED]

The fifth container is labeled "#4, right obturator" and contains multiple fragments of fibroadipose tissue, measuring 4 x 3 x 1.5 cm in aggregate. Multiple lymph nodes ranging up to 3 cm in greatest dimension are present within the tissue. Labeled C1 and C2. [REDACTED]

The sixth container is labeled "#5, left external iliac lymph nodes" and contains multiple fragments of fibroadipose tissue, measuring 4 x 4 x 1 cm in aggregate. Within the tissue, lymph nodes are present and measure up to 2 cm in greatest dimension. Labeled D1 and D2. [REDACTED]

The seventh container is labeled "#6, left obturator lymph nodes" and contains multiple fragments of fibroadipose tissue, measuring 3 x 2 x 1 cm in aggregate. Multiple lymph nodes are present, the largest measuring 2 x 1.3 x 0.5 cm. [REDACTED]

The eighth container is labeled "#7, periaortic lymph nodes" and contains a single fibroadipose tissue fragment, measuring 3.5 x 2 x 0.7 cm. Lymph nodes are present within this tissue and measure up to 1.3 cm in greatest dimension. [REDACTED]

The ninth container is labeled "omentum" and contains an omentum that measures 29 x 8 x 1 cm. The specimen consists entirely of multiple lobules of yellow fat, interconnected by a loose fibrous stroma. No tumor is evident anywhere on the specimen. Labeled Q1 through Q5, random sections. [REDACTED]

The tenth container is labeled "#10, right gutter" and contains a single pink-tan tissue fragment, measuring 0.4 x 0.3 x 0.2 cm. Labeled H. [REDACTED]

The eleventh container is labeled "#11, left gutter" and contains a single pink-white tissue fragment, measuring 0.5 x 0.2 x 0.1 cm. Labeled I. [REDACTED]

The twelfth container is labeled "#12, left gutter" and contains a single pink and brown tissue fragment, measuring 0.4 x 0.3 x 0.2

[page 7 of 8]
GROSS (continued)

cm. Labeled J. [REDACTED]

The thirteenth container is labeled "#13 right gutter" and contains a single pink-white tissue fragment, measuring 0.9 x 0.3 x 0.2 cm. [REDACTED]

The fourteenth container is labeled "#9, diaphragmatic biopsy" and contains two strips of fibrous tissue, measuring 1.3 and 1 cm in greatest dimension. Labeled L. [REDACTED]

The fifteenth container is labeled "#14, anterior cul de sac" and contains a single yellow-tan tissue fragment, measuring 0.5 x 0.2 x 0.1 cm. [REDACTED]

The sixteenth container is labeled "#15, anterior cul de sac" and contains a single tan-white tissue fragment, measuring 0.6 x 0.2 x 0.1 cm. [REDACTED]

The seventeenth container is labeled "#16, posterior cul de sac" and contains a single red-brown tissue fragment, measuring 0.6 x 0.5 x 0.3 cm. [REDACTED]

The eighteenth container is labeled "#17, posterior cul de sac" and contains a single fragment of brown tissue that is irregular and measures 2 x 1 x 0.3 cm. [REDACTED]

COMMENT

Additional sections of the nodule on the serosal surface of the uterus will be submitted and the results reported in an addendum. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

- 1a. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma ([REDACTED])
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary ([REDACTED])
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests) ([REDACTED])
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated) ([REDACTED])
6. Tumor IS identified on the ovarian surface(s). [REDACTED]
7. Tumor DOES NOT invade the mesovarium. [REDACTED]

[page 8 of 8]
COMMENT (continued)

8. Tumor is present in the right fallopian tube, replacing the lumen.
9. Tumor DOES NOT directly invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum is ABSENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is microscopic. (Enter "0" if no implants.)
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are ABSENT.
17. The total number of regional lymph nodes examined is 25.
18. The total number of metastatically-involved regional lymph nodes is 0.
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME
T3a

FIGO SCHEME
IIIA

DEFINITION
Microscopic peritoneal
metastasis beyond true pelvis

THE REGIONAL LYMPH NODES are classified as:
NO (Nodes are free of metastases)

THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE requires clinical information.

{End of Report}

Source: NCI Genomic Data Commons file ecdfef95-e3e5-4474-a228-6cb3118c43f4 (TCGA-24-2023.2A255FA6-65CD-4FB7-9D08-1B6AADD6682B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).